Gene-level copy-number profile of tumor specimen TCGA-78-8660-01A from TCGA case TCGA-78-8660, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.6 years (25,422 days).
Specimen TCGA-78-8660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6c07995f-b919-493a-9254-76f7d79598cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-8660-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4408b1b3-4ef1-48d2-8a95-ae1e479ca66e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,733; copy number 2: 36,124; copy number 3: 7,685; copy number 4: 131; copy number 5: 67; copy number 6: 43; copy number 10: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-8660-01A-11D-2389-01): tumor purity 0.33, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 146 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:35,826,338–37,579,125, 36 genes, copy number 10 (within-gene range 4–10): BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1.
- chr14:49,552,633–51,096,061, 67 genes, copy number 5 (broad region; genes not listed).
- chr14:53,011,971–55,411,830, 43 genes, copy number 6 (within-gene range 3–6): AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1, AL365295.1, AL365295.2, AL163953.1, RPS3AP46, LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1.

Autosomal genes at a single copy (total copy number 1): 13,318. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
